Gene-level copy-number profile of tumor specimen MP2PRT-PATNLF-TTP1-A from MP2PRT case MP2PRT-PATNLF, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 2.7 years (1,004 days).
Specimen MP2PRT-PATNLF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 94a670e3-342f-455d-b996-b95d785f686f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATNLF-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/ed02097b-9278-4065-831f-2a9cf4db7af1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 2,850; copy number 2: 42,726; copy number 3: 11,223; copy number 4: 2,095; copy number 5: 9.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:109,062,486–109,076,003, 1 gene, copy number 5: TAF13.
- chr1:110,362,851–110,391,082, 2 genes, copy number 5 (within-gene range 4–5): SLC16A4, AL355488.1.
- chr1:111,280,059–111,286,116, 1 gene, copy number 5: CHIAP2.
- chr1:116,278,606–116,278,821, 1 gene, copy number 5: U3.
- chr1:119,834,870–119,896,515, 4 genes, copy number 5: NBPF7, PFN1P9, NOTCH2P1, ADAM30.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
